Somatic mutation profile of tumor specimen TCGA-HT-7692-01A (aliquot TCGA-HT-7692-01A-12D-2253-08) from TCGA case TCGA-HT-7692, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.1 years (15,727 days).
Specimen TCGA-HT-7692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a3e774e-87bc-403b-af47-832e649cc0be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7692-10A (Blood Derived Normal), aliquot TCGA-HT-7692-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50ae1d56-dcd5-40fd-ba8e-0b4cf0bfb83d

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 14, Silent 8, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs1012214184, COSV60099298; called by muse, mutect2
- CNBD2 | c.1660T>C p.Y554H (on ENST00000373973 / NM_001365709.1; = p.Y550H on NM_080834.4) | Missense Mutation (SNP) | VAF 159/360 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV62587297; called by muse, mutect2, varscan2
- FBH1 | c.3017G>A p.R1006H (on ENST00000362091 / NM_178150.3; = p.R1057H on NM_032807.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1337845136, COSV62983228; called by muse, mutect2, varscan2
- FDX2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58533398; called by muse, mutect2, varscan2
- FGFR2 | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60651437; called by muse, mutect2, varscan2
- KMT5B | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV58567569; called by muse, mutect2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as rs776720499; called by mutect2, pindel
- MUC5B | c.12806C>T p.P4269L | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs778718756, COSV71592420; called by muse, mutect2, varscan2
- OR2C3 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1225334626, COSV63575463; called by muse, mutect2, varscan2
- OR5A1 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs768465459, COSV57376169, COSV57377743; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1285A>T p.K429* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV53453777; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs201435531, COSV53447995; called by muse, mutect2, varscan2
- SPATA31E1 | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.596); catalogued as COSV57793096; called by muse, mutect2, varscan2
- TNFRSF13B | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.142); catalogued as COSV55428707; called by muse, mutect2, varscan2
- PTX3 | c.9_11del p.L4del | In Frame Del (DEL) | VAF 60/147 reads (41%) | called by mutect2, pindel, varscan2
- SH3RF1 | c.2647_2654del p.S883Gfs*46 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- BNIP1 | c.441G>A p.R147= | Silent (SNP) | VAF 106/254 reads (42%) | catalogued as COSV51571081; called by muse, mutect2, varscan2
- KAT14 | c.2334G>A p.L778= | Silent (SNP) | VAF 58/126 reads (46%) | catalogued as COSV66608273; called by muse, mutect2, varscan2
- NES | c.1629A>G p.K543= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV63961555; called by muse, mutect2, varscan2
- OR10G8 | c.864C>T p.T288= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV70908643; called by muse, mutect2
- OR7D2 | c.430C>T p.L144= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as rs781141871, COSV100712950, COSV60140350; called by muse, mutect2
- PPP6R3 | c.1270T>C p.L424= (on ENST00000393800 / NM_001352375.2; = p.L373= on NM_018312.5) | Silent (SNP) | VAF 79/170 reads (46%) | catalogued as rs766930354, COSV55729863; called by muse, mutect2, varscan2
- SHBG | c.849T>C p.D283= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV52647208; called by muse, mutect2, varscan2
- SLC5A3 | c.735A>G p.K245= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as rs769899447, COSV62971138; called by muse, mutect2, varscan2
